Somatic mutation profile of tumor specimen TCGA-YL-A8HK-01A (aliquot TCGA-YL-A8HK-01A-11D-A364-08) from TCGA case TCGA-YL-A8HK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.8 years (21,850 days).
Specimen TCGA-YL-A8HK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6418bef9-937f-4578-b76b-5056757cb912.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8HK-10A (Blood Derived Normal), aliquot TCGA-YL-A8HK-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a66918a0-b4fe-4eb1-866f-c9d6979ee52e

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 11, Silent 8, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as rs142686791, COSV99360299; called by muse, mutect2, varscan2
- CCRL2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs767420503, COSV62193229; called by muse, mutect2, varscan2
- CDK7 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99841554; called by muse, mutect2, varscan2
- DEPDC7 | c.628C>T p.R210C (on ENST00000241051 / NM_001077242.2; = p.R201C on NM_139160.2) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749658035, COSV53806174, COSV53807601; called by muse, mutect2, varscan2
- FANCF | c.62C>G p.T21S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs765672591, COSV100541779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GARNL3 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332708016, COSV59226978; called by muse, mutect2, varscan2
- LRP1 | c.9914G>A p.C3305Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1482165787, COSV99674714; called by muse, mutect2, varscan2
- OR7A10 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.017); catalogued as rs755251603, COSV50166663; called by muse, mutect2, varscan2
- RNF40 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV100221925, COSV100222110; called by muse, mutect2, varscan2
- SLC2A13 | c.1547A>G p.Y516C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99786035; called by muse, mutect2, varscan2
- TG | c.7150G>A p.A2384T | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99599386; called by muse, mutect2
- RPL27 | c.219dup p.V74Sfs*3 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- CRNN | c.291C>T p.C97= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as rs775046138, COSV55121239; called by muse, mutect2, varscan2
- DPPA2 | c.174C>T p.Y58= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV72118394; called by muse, mutect2, varscan2
- FLG | c.6678C>G p.G2226= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV100910670, COSV64246972; called by muse, mutect2, varscan2
- GAS2L3 | c.1837C>T p.L613= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99902712; called by muse, mutect2, varscan2
- GRIN2B | c.3957G>A p.P1319= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs141730031; ClinVar: likely benign; called by muse, mutect2, varscan2
- HADH | c.255C>T p.N85= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs746650397; called by muse, mutect2
- PAMR1 | c.1527G>C p.L509= (on ENST00000619888 / NM_001001991.3; = p.L526= on NM_015430.4) | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs1390083439, COSV99552197; called by muse, mutect2, varscan2
- SALL4 | c.1767C>T p.T589= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs201329321, COSV53853039; called by muse, mutect2, varscan2
